Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A2IU, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A2IU-01A (Primary Tumor).

[page 1 of 2]
Patient: _____

Surg Path

CLINICAL HISTORY:
Not provided.

Case (circle):		
Revised: QUA, IPFD		

GROSS EXAMINATION:

A. "Right breast and axillary contents", received fresh. A 1,330 grams, 33.0 x 16.0 x 6.8 cm. The specimen is breast with attached fibrofatty tissue. The breast itself measures 27.5 x 16.0 x 6.8, the axillary tail measures 10.5 x 9.0 x 3.5 cm. The attached ellipse of skin measures 24 x 12.2 cm, with a 4.0 cm areola and a 1.4 cm nipple. The surgical margin of the specimen are inked and the specimen is sliced serially. There is a 5.0 x 5.0 x 2.8 cm firm, ill defined mass in the central region of the breast. It is 2.2 cm from the closest (posterior) margin.

BLOCK SUMMARY:

- A1- cross sections from the nipple.
- A2- hard mass with closest surgical margin.
- A3-A6- representative sections of the mass.
- A7- representative sections from the upper outer quadrant.
- A8- representative sections from the lower outer quadrant.
- A9- representative sections from the lower inner quadrant.
- A10- representative sections from the upper inner quadrant.
- A11- seven lymph node candidates from the proximal axillary fat.
- A12- seven lymph node candidates from the middle axillary fat.
- A13- six lymph node candidates from the middle axillary fat.
- A14- four lymph node candidates from the distal axillary fat.
- A15- one lymph node candidate from the distal axillary fat, bisected.
- A16- four lymph node candidates from the distal axillary fat.
- A17- one lymph node candidate from the distal axillary fat.
- A18- five lymph node candidates from the distal axillary fat.

1CD-0-3

Carcinoma, infiltrating

lobular, NOS

8520/3

Site: breast, NOS C50.9

w 7/24/11

DIAGNOSIS:

A. "RIGHT BREAST AND AXILLARY CONTENTS" (MODIFIED RADICAL MASTECTOMY):

INFILTRATING CARCINOMA PRESENT, HISTOLOGIC TYPE LOBULAR.

N.S.A.B.P. NUCLEAR GRADE 2 OF 3.

N.S.A.B.P. HISTOLOGIC GRADE: NOT APPLICABLE.

GROSS TUMOR SIZE: 5.0 X 5.0 X 2.8 CM.

SIZE OF INVASIVE COMPONENT 5.0 X 5.0 X 2.8 CM.

LOCATION OF THE TUMOR, CENTRAL.

LYMPHATIC/VASCULAR INVASION ABSENT.

MULTIFOCAL TUMOR PRESENT, EXTENSIVE, SEE COMMENT.

IN SITU CARCINOMA ABSENT.

NIPPLE STATUS, FREE OF TUMOR.

SKIN STATUS, FREE OF TUMOR.

MUSCLE STATUS, NOT SAMPLED.

STATUS OF NON-NEOPLASTIC BREAST TISSUE: BENIGN FIBROCYSTIC CHANGES.

SURGICAL MARGIN STATUS: NEGATIVE.

LYMPH NODE STATUS: TWENTY-EIGHT AXILLARY LYMPH NODES, NO EVIDENCE OF MALIGNANCY (0/28).

ESTROGEN/PROGESTERONE RECEPTOR AND CELL CYCLE ANALYSIS PENDING.

METHODOLOGY: IMMUNOHISTOCHEMISTRY, PARAFFIN BLOCK A3.

RESULTS WILL BE ISSUED IN AN ADDENDUM.

[page 2 of 2]
COMMENT: There is very extensive multifocal/multicentric disease, with random sections distant from the main tumor mass showing foci of infiltrating lobular carcinoma involving all four quadrants of the breast.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

ADDENDUM 1:

Tissue was sent to the _____ for assay of the estrogen and progesterone receptors. The estrogen receptor activity was judged to be positive with an estimated FMOL value of 30. The progesterone receptor activity was judged as positive with an estimated FMOL of value of 101. Please refer to _____ for a complete report.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 412a4169-63ef-4ae3-a520-f7eccca163f6 (TCGA-B6-A2IU.EE769039-220E-4158-8999-09F17AFB4C46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).